Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6436, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6436-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

(A) TEETH:

Teeth identified, gross identification only.

(B) LEFT NECK DISSECTION, LEVEL I "A":

One lymph node, no tumor present (0/1).

(C) LEFT PARTIAL GLOSSECTOMY::

INVASIVE SQUAMOUS CARCINOMA -- Well differentiated

Tumor Features:

Gross: Exophytic

Size: 7.2 cm in largest dimension

Invasion: Present, depth 0.6 cm

Tumor Border: infiltrative

Perineural Invasion: Absent

Vascular Invasion: Absent

Lymphocyte Infiltration: Absent

Mucosal Margin: (en-face) Negative for invasive carcinoma

Deep Margin: (radial) Negative for invasive carcinoma

Dysplasia at Margin: Absent

(D) LEFT NECK DISSECTION, LEVEL I:

Seven lymph nodes, no tumor present (0/7).

Salivary tissue, no tumor present.

(E) LEFT NECK DISSECTION, LEVEL II:

Twenty-two lymph nodes, no tumor present (0/22).

(F) LEFT NECK DISSECTION, LEVEL III:

Ten lymph nodes, no tumor present (0/10).

Entire report and diagnosis completed by [REDACTED]

GROSS DESCRIPTION

(A) TEETH - Multiple fragments of white-tan teeth. The specimen is for gross examination only. [REDACTED]

(B) LEFT NECK DISSECTION, LEVEL I "A" - A 0.9 x 0.5 x 0.4 cm lymph node. The specimen is submitted entirely in cassette B. [REDACTED]

(C) LEFT PARTIAL GLOSSECTOMY - Specimen consists of a portion of tongue (7.5 x 6.7 x 4.5 cm) with a centrally placed exophytic verrucous tumor (7.2 x 6.3 x 2.5 cm). The closest mucosal margin is posteriorly towards the base of tongue (0.4 cm). The tumor appears to possibly superficially invade the muscle of the tongue, but the deep margin is widely free of tumor. The lingual nerve is identified by the surgeon and is grossly unremarkable.

INK CODE: Black - deep margin.

[page 2 of 2]
SECTION CODE: C1, superior/anterior mucosal margin for frozen section; C2, superior mid, mucosal margin for frozen section; C3, superior posterior mucosal margin for frozen section; C4, base of tongue, medial mucosal margin for frozen section; C5, base of tongue, lateral mucosal margin for frozen section; C6, lateral posterior mucosal margin for frozen section; C7, lateral mid mucosal margin for frozen section; C8, lateral anterior mucosal margin for frozen section; C9, anterior mucosal margin for frozen section; C10, representative sections of the lingual for frozen section; C11, representative section of tumor with closest deep margin for frozen section; C12-C20, representative sections of tumor with underlying tongue, submitted anterior to posterior (deep margin in C13-C15).

*FS/DX: NO TUMOR PRESENT AT MARGINS.

(D) LEFT NECK DISSECTION LEVEL I - An unoriented, tan-pink fragment of fibrofatty tissue (7.0 x 6.5 x 2.5 cm). Dissection reveals a tan, grossly unremarkable submandibular gland (6.0 x 5.0 x 2.5 cm). Nine lymph nodes are identified, ranging from (0.2 x 0.1 x 0.1 cm to 2.0 x 1.5 x 1.0 cm).

SECTION CODE: D1, five lymph nodes; D2, three lymph nodes; D3, D4, one lymph node, serially sectioned; D5, representative section of submandibular gland.

(E) LEFT NECK DISSECTION LEVEL II - An unoriented, tan-pink fragment of fibrofatty tissue (9.0 x 5.5 x 2.0 cm). Dissection reveals 24 lymph nodes ranging from (0.1 x 0.1 x 0.1 cm to 3.0 x 1.5 x 1.0 cm).

SECTION CODE: E1, six lymph nodes; E2, five lymph nodes; E3, three lymph nodes; E4, three lymph nodes; E5, two lymph nodes; E6, one lymph node, trisected; E7, one lymph node, serially sectioned; E8, one lymph node, trisected; E9, one lymph node, trisected; E10, E11, one lymph node, serially sectioned.

(F) LEFT NECK DISSECTION LEVEL III - An unoriented, tan-pink fragment of fibrofatty tissue (7.0 x 4.5 x 1.5 cm). Dissection reveals 10 lymph nodes ranging from (0.3 x 0.2 x 0.2 cm to 2.5 x 2.0 x 1.5 cm).

SECTION CODE: F1, four lymph nodes; F2, three lymph nodes; F3, two lymph nodes; F4, one lymph node, serially sectioned.

CLINICAL HISTORY

None given.

SNOMED CODES

T-53000, M-80703

"Some tests reported here may have been developed and performance characteristics determined by Pathology and Laboratory Medicine. These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Released by:

Page 2 of 2	
Surgical Pathology Report	
File under: Pathology	

Source: NCI Genomic Data Commons file f30d8b7a-a8d5-4fb1-bbf2-706d4c6751f4 (TCGA-CV-6436.951CAAAC-31EB-434C-804A-7B9DA09A64FB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).